Somatic mutation profile of tumor specimen TCGA-WK-A8XQ-01A (aliquot TCGA-WK-A8XQ-01A-11D-A37C-09) from TCGA case TCGA-WK-A8XQ, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 57.2 years (20,891 days).
Specimen TCGA-WK-A8XQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 542edb2c-3566-4340-855f-c3f88aeee485.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WK-A8XQ-10A (Blood Derived Normal), aliquot TCGA-WK-A8XQ-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0581d54f-809d-46d7-90e2-d8b78f340dfc

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, RNA 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.15319G>A p.V5107I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1272253804, COSV101316258; called by muse, mutect2, varscan2
- C2orf73 | c.687G>T p.Q229H | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV100471395; called by muse, mutect2
- CREB3L3 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.334); catalogued as COSV50250209; called by muse, mutect2, varscan2
- DAAM1 | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 5/68 reads (7%) | catalogued as COSV100658578; called by muse, mutect2
- DNAJC1 | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1047566210, COSV100981399; called by muse, mutect2, varscan2
- MAP7D1 | c.142C>G p.P48A | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100294661, COSV60216174; called by muse, mutect2, varscan2
- OR5P2 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as rs372220227; called by muse, mutect2, varscan2
- PSMD3 | c.890C>G p.A297G | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV99227959; called by muse, mutect2, varscan2
- PWWP3B | c.1744T>C p.W582R | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100531477; called by muse, varscan2
- RPA1 | c.768T>A p.Y256* | Nonsense Mutation (SNP) | VAF 24/33 reads (73%) | catalogued as COSV54613242, COSV99628208; called by muse, mutect2, varscan2
- SETX | c.4010G>T p.R1337I | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV99810424; called by muse, mutect2, varscan2
- SFXN2 | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201424155, COSV100882759; called by muse, mutect2, varscan2
- TMPRSS11D | c.271T>A p.S91T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99384883; called by muse, mutect2
- UGT2B11 | c.474G>T p.E158D | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as COSV101485273; called by muse, mutect2, varscan2
- ZNF285 | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV100450073; called by muse, mutect2, varscan2
- ZNF589 | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV100685744; called by muse, mutect2, varscan2
- FOXD4L4 | c.226G>C p.G76R | Missense Mutation (SNP) | VAF 104/423 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); called by muse, varscan2
- CHD9 | c.4689A>G p.G1563= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV99529485; called by muse, mutect2, varscan2
- KRT27 | c.924A>G p.K308= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV100053320; called by muse, mutect2, varscan2
- OTX1 | c.915T>A p.G305= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV99246436; called by muse, mutect2, varscan2
- RIMS1 | c.2092C>A p.R698= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV99328921; called by muse, mutect2, varscan2
- VWF | c.693C>T p.T231= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV54629901, COSV54636183; called by muse, mutect2, varscan2
- YWHAG | c.708C>T p.D236= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as COSV100297395; called by muse, mutect2, varscan2
- HERC2P3 | n.364T>A | RNA (SNP) | VAF 105/334 reads (31%) | called by muse, mutect2, varscan2
- TUBB7P | n.43C>T | RNA (SNP) | VAF 70/156 reads (45%) | called by muse, varscan2
